Somatic mutation profile of tumor specimen MP2PRT-PAUDCM-TMP1-A (aliquot MP2PRT-PAUDCM-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUDCM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.9 years (2,898 days).
Specimen MP2PRT-PAUDCM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 009713ec-8ebe-44ea-b1c8-b16c2c774b7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUDCM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUDCM-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2481dd23-6bbc-4d25-b982-358966837dbe

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 199/481 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 129/305 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064794311, CM973401, COSV52661102, COSV52687307, COSV99402633; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ARHGEF4 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 121/300 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs201813341, COSV58122722; called by muse, mutect2, varscan2
- SATB1 | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58667618; called by muse, mutect2, varscan2
- TPPP | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 36/355 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.541); catalogued as rs1390144157; called by muse, mutect2
- CABP5 | c.261T>G p.D87E | Missense Mutation (SNP) | VAF 156/358 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP11B1 | c.1487T>C p.L496P | Missense Mutation (SNP) | VAF 118/343 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- IGHV3-53 | c.348_349insAGGTGTGGCTGGGAAA | In Frame Ins (INS) | VAF 4/71 reads (6%) | called by mutect2, pindel
- IRF2BPL | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 258/579 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR1 | c.1801G>A p.V601M | Missense Mutation (SNP) | VAF 135/303 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CDH1 | c.1170C>T p.N390= | Silent (SNP) | VAF 45/432 reads (10%) | catalogued as rs766505270, COSV99028647; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2
- FOXP2 | c.360C>A p.A120= | Silent (SNP) | VAF 27/457 reads (6%) | called by muse, mutect2
